Somatic mutation profile of tumor specimen TCGA-BS-A0TE-01A (aliquot TCGA-BS-A0TE-01A-11D-A10B-09) from TCGA case TCGA-BS-A0TE, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Corpus uteri; FIGO stage: Stage IVB; Tumor grade: G3; Age at diagnosis: 35.5 years (12,983 days).
Specimen TCGA-BS-A0TE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3ac6c0c8-917f-4f79-9db0-8db5774c6abc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BS-A0TE-10A (Blood Derived Normal), aliquot TCGA-BS-A0TE-10A-01D-A10B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8c494cf1-9cac-4971-a564-ae9e1bd1d395

The open-access MAF lists 368 somatic variants for this specimen: 267 protein-altering or splice-affecting, 96 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 196, Silent 96, Frame Shift Del 37, Nonsense Mutation 16, Frame Shift Ins 10, Splice Site 5, RNA 3, Intron 2, In Frame Del 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP1S1 | c.364del p.D122Mfs*11 | Frame Shift Del (DEL) | VAF 43/214 reads (20%) | catalogued as rs767358930; ClinVar: likely pathogenic; called by mutect2, varscan2
- CDH1 | c.377del p.P126Rfs*89 | Frame Shift Del (DEL) | VAF 43/122 reads (35%) | catalogued as rs1060501215; ClinVar: pathogenic; called by mutect2, varscan2
- LARP7 | c.1213dup p.T405Nfs*26 | Frame Shift Ins (INS) | VAF 58/174 reads (33%) | catalogued as rs750946801; ClinVar: likely pathogenic; called by mutect2, varscan2
- NF1 | c.233del p.N78Ifs*7 | Frame Shift Del (DEL) | VAF 85/171 reads (50%) | catalogued as rs1438566555; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PCDH19 | c.1091dup p.Y366Lfs*10 | Frame Shift Ins (INS) | VAF 12/61 reads (20%) | catalogued as rs758946412; ClinVar: pathogenic; called by mutect2, varscan2
- TSC1 | c.2672del p.N891Tfs*40 | Frame Shift Del (DEL) | VAF 47/219 reads (21%) | catalogued as rs118203724, CD1111250, COSV53764493; ClinVar: not provided / pathogenic; called by mutect2, pindel, varscan2
- ABCA12 | c.1841T>G p.L614R (on ENST00000272895 / NM_173076.3; = p.L296R on NM_015657.3) | Missense Mutation (SNP) | VAF 136/289 reads (47%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.453); catalogued as COSV55965245; called by muse, mutect2, varscan2
- ABCC5 | c.3269del p.L1090Cfs*26 | Frame Shift Del (DEL) | VAF 34/142 reads (24%) | catalogued as rs749943218; called by mutect2, varscan2
- ABCD1 | c.1504C>T p.H502Y | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV54386182; called by muse, mutect2, varscan2
- ABHD13 | c.560T>A p.I187N | Missense Mutation (SNP) | VAF 46/170 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV65535161; called by muse, mutect2, varscan2
- ACACB | c.6455T>C p.M2152T | Missense Mutation (SNP) | VAF 45/174 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV58138551; called by muse, mutect2, varscan2
- ADAMTS7 | c.841C>A p.P281T | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV66308110; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4593C>A p.D1531E | Missense Mutation (SNP) | VAF 158/337 reads (47%) | SIFT tolerated (0.78); PolyPhen benign (0.015); catalogued as COSV54455509; called by muse, mutect2, varscan2
- ADCY2 | c.833T>A p.F278Y | Missense Mutation (SNP) | VAF 50/232 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57881924, COSV57903661; called by muse, mutect2, varscan2
- ADCY6 | c.2166+2T>C p.X722_splice | Splice Site (SNP) | VAF 52/207 reads (25%) | catalogued as COSV57168820; called by muse, mutect2, varscan2
- ADGRL3 | c.3358A>G p.I1120V (on ENST00000506720 / NM_001322402.2; = p.I1052V on NM_015236.6) | Missense Mutation (SNP) | VAF 118/381 reads (31%) | SIFT tolerated (0.74); PolyPhen benign (0.16); catalogued as rs376395055; called by muse, mutect2, varscan2
- AHNAK | c.12380C>T p.P4127L | Missense Mutation (SNP) | VAF 69/223 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375049429; called by muse, mutect2, varscan2
- AKAP9 | c.3485A>G p.Q1162R | Missense Mutation (SNP) | VAF 72/327 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.259); catalogued as COSV100662259, COSV62350660; called by muse, mutect2
- ANGPT1 | c.342G>C p.Q114H | Missense Mutation (SNP) | VAF 189/514 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as rs200040737; called by muse, mutect2, varscan2
- ANK3 | c.3667C>T p.P1223S (on ENST00000280772 / NM_001320874.2; = p.P357S on NM_001149.3) | Missense Mutation (SNP) | VAF 15/238 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV55065954, COSV99780238; called by muse, mutect2
- ANKMY1 | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs201252509, COSV56036648; called by muse, mutect2, varscan2
- ARHGEF3 | c.16T>A p.Y6N | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.037); catalogued as COSV56328776; called by muse, mutect2, varscan2
- ARID1A | c.5548del p.D1850Tfs*33 | Frame Shift Del (DEL) | VAF 9/47 reads (19%) | catalogued as COSV61389445; called by mutect2, pindel, varscan2
- ASPM | c.7346A>G p.H2449R | Missense Mutation (SNP) | VAF 47/171 reads (27%) | SIFT tolerated (0.77); PolyPhen benign (0.031); catalogued as rs373426629; called by muse, mutect2, varscan2
- ATL2 | c.326T>C p.F109S | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60053687; called by muse, mutect2, varscan2
- ATP11C | c.3077A>G p.H1026R | Missense Mutation (SNP) | VAF 74/286 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59567706; called by muse, mutect2, varscan2
- BACH1 | c.432del p.K144Nfs*22 | Frame Shift Del (DEL) | VAF 183/359 reads (51%) | catalogued as rs748639705; called by mutect2, pindel, varscan2
- BAG2 | c.278C>T p.T93I | Missense Mutation (SNP) | VAF 43/213 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV58098442; called by muse, mutect2, varscan2
- BAZ2B | c.541G>C p.V181L | Missense Mutation (SNP) | VAF 214/472 reads (45%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.079); catalogued as COSV58601714, COSV58604378; called by muse, mutect2, varscan2
- BBX | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 131/330 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.436); catalogued as rs140692011, COSV57885733, COSV57888125; called by muse, mutect2, varscan2
- BMP4 | c.221G>A p.S74N | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.935); catalogued as COSV55416442; called by muse, mutect2
- C12orf50 | c.1162T>C p.W388R | Missense Mutation (SNP) | VAF 49/240 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1243706881, COSV53896598; called by muse, mutect2, varscan2
- C1GALT1C1L | c.818T>C p.I273T | Missense Mutation (SNP) | VAF 33/299 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV56756816; called by muse, mutect2, varscan2
- C4orf33 | c.346G>T p.G116C | Missense Mutation (SNP) | VAF 52/161 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55416338; called by muse, mutect2, varscan2
- CACNA1F | c.5684C>T p.A1895V | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as COSV59903319; called by muse, mutect2, varscan2
- CAMTA1 | c.3652A>G p.N1218D | Missense Mutation (SNP) | VAF 25/34 reads (74%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.411); catalogued as COSV57910199; called by muse, mutect2, varscan2
- CASS4 | c.1709C>T p.P570L | Missense Mutation (SNP) | VAF 98/241 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64387179; called by muse, mutect2, varscan2
- CD247 | c.207C>A p.N69K | Missense Mutation (SNP) | VAF 44/69 reads (64%) | SIFT deleterious (0.02); PolyPhen benign (0.051); catalogued as COSV62978982; called by muse, mutect2, varscan2
- CD276 | c.1376C>A p.P459H (on ENST00000318443 / NM_001024736.2; = p.P241H on NM_025240.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 100/402 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV59204322; called by muse, mutect2, varscan2
- CDH1 | c.284A>T p.Q95L | Missense Mutation (SNP) | VAF 10/297 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.124); catalogued as COSV55735759; called by muse, mutect2
- CDH9 | c.2106G>T p.R702S | Missense Mutation (SNP) | VAF 194/422 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.196); catalogued as rs776933344, COSV50321821; called by muse, mutect2, varscan2
- CDH9 | c.170G>T p.W57L | Missense Mutation (SNP) | VAF 82/344 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV50322003; called by muse, mutect2, varscan2
- CEP68 | c.1096C>T p.P366S | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.022); catalogued as COSV53125805; called by muse, mutect2, varscan2
- CHCHD2 | c.52C>T p.R18W | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.649); catalogued as rs780172272, COSV68170037; called by muse, mutect2
- CLPX | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 129/560 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV55643619, COSV55645334; called by muse, mutect2, varscan2
- CNR1 | c.26C>A p.A9E | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV62988870; called by muse, mutect2
- COL11A1 | c.4249-1G>T p.X1417_splice | Splice Site (SNP) | VAF 4/19 reads (21%) | catalogued as COSV62178622, COSV62188219; called by muse, mutect2
- CPED1 | c.1076T>C p.F359S | Missense Mutation (SNP) | VAF 165/961 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV60006179; called by muse, mutect2, varscan2
- CSMD3 | c.4678C>T p.L1560F (on ENST00000297405 / NM_001363185.1; = p.L1456F on NM_052900.3) | Missense Mutation (SNP) | VAF 72/396 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52228120, COSV52350352; called by muse, mutect2, varscan2
- CTNND2 | c.856G>A p.A286T | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as COSV58902515; called by muse, mutect2
- DENND5A | c.2684del p.K895Sfs*7 | Frame Shift Del (DEL) | VAF 60/205 reads (29%) | catalogued as rs1208100549; called by mutect2, pindel, varscan2
- DMD | c.3098C>T p.S1033F | Missense Mutation (SNP) | VAF 57/310 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.272); catalogued as rs377415288, CD093451, COSV63750702; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH1 | c.5570G>A p.G1857D | Missense Mutation (SNP) | VAF 29/47 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1286037410, COSV70231322; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 149/257 reads (58%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOCK7 | c.905T>C p.F302S | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52011955; called by muse, mutect2, varscan2
- DUSP11 | c.382C>T p.R128* | Nonsense Mutation (SNP) | VAF 80/437 reads (18%) | catalogued as rs754705080, COSV55595147, COSV99730981; called by muse, mutect2, varscan2
- DVL3 | c.1187C>A p.P396H | Missense Mutation (SNP) | VAF 136/301 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV57457003; called by muse, mutect2, varscan2
- EDC4 | c.2705C>T p.P902L | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT tolerated (0.49); PolyPhen benign (0.115); catalogued as COSV59303129; called by muse, mutect2, varscan2
- EFCAB3 | c.207C>A p.F69L | Missense Mutation (SNP) | VAF 22/430 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59503022; called by muse, mutect2
- EFHC2 | c.1170A>T p.K390N | Missense Mutation (SNP) | VAF 19/535 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.152); catalogued as COSV69554283; called by muse, mutect2
- EHBP1 | c.1035A>G p.I345M | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.068); catalogued as COSV50424994; called by muse, mutect2, varscan2
- EPS8L2 | c.1412del p.P471Rfs*49 | Frame Shift Del (DEL) | VAF 130/191 reads (68%) | catalogued as COSV59350488; called by mutect2, varscan2
- ERCC4 | c.2390G>T p.R797I | Missense Mutation (SNP) | VAF 93/270 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.177); catalogued as COSV61311389, COSV61312724; called by muse, mutect2, varscan2
- EXT1 | c.1918G>A p.A640T | Missense Mutation (SNP) | VAF 245/668 reads (37%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV65481640; called by muse, mutect2, varscan2
- FAM47B | c.385C>A p.H129N | Missense Mutation (SNP) | VAF 66/245 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.201); catalogued as COSV61455137; called by muse, mutect2, varscan2
- FAM47C | c.1694C>T p.T565I | Missense Mutation (SNP) | VAF 42/180 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV63727981; called by muse, mutect2, varscan2
- FAM83C | c.1187G>A p.R396H | Missense Mutation (SNP) | VAF 59/359 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.01); catalogued as rs920551165, COSV65583610; called by muse, mutect2, varscan2
- FAT3 | c.3425A>G p.N1142S | Missense Mutation (SNP) | VAF 66/118 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53118558; called by muse, mutect2, varscan2
- FBXL3 | c.649C>A p.L217I | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.696); catalogued as COSV62918970; called by muse, mutect2, varscan2
- FETUB | c.437del p.K146Rfs*4 | Frame Shift Del (DEL) | VAF 75/197 reads (38%) | catalogued as rs748969702; called by mutect2, varscan2
- FUS | c.323G>A p.S108N | Missense Mutation (SNP) | VAF 6/111 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV54218252; called by muse, mutect2
- GALNT5 | c.1255G>T p.G419* | Nonsense Mutation (SNP) | VAF 25/347 reads (7%) | catalogued as COSV52038934; called by muse, mutect2
- GAS2L3 | c.133G>C p.A45P | Missense Mutation (SNP) | VAF 76/358 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV57157881; called by muse, mutect2, varscan2
- GLRA2 | c.644G>C p.G215A | Missense Mutation (SNP) | VAF 155/555 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.667); catalogued as COSV54343368; called by muse, mutect2, varscan2
- GNL3L | c.391-1G>T p.X131_splice | Splice Site (SNP) | VAF 20/462 reads (4%) | catalogued as COSV60576975; called by muse, mutect2
- GOLIM4 | c.1501G>T p.G501* | Nonsense Mutation (SNP) | VAF 86/481 reads (18%) | catalogued as COSV58330519; called by muse, mutect2, varscan2
- GPER1 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT tolerated (0.78); PolyPhen benign (0.021); catalogued as rs770036304, COSV52469081; called by muse, mutect2, varscan2
- GPR155 | c.628G>A p.G210R | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.71); catalogued as rs553833504, COSV55039957; called by muse, mutect2, varscan2
- GRIA4 | c.286G>T p.G96* | Nonsense Mutation (SNP) | VAF 200/328 reads (61%) | catalogued as COSV56905172; called by muse, mutect2, varscan2
- GRM1 | c.566G>A p.S189N | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as COSV51184800; called by muse, mutect2, varscan2
- GRXCR1 | c.502G>A p.V168I | Missense Mutation (SNP) | VAF 185/302 reads (61%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.637); catalogued as rs577521620, COSV67670049; called by muse, mutect2, varscan2
- GSG1 | c.823G>T p.E275* (on ENST00000651961 / NM_001080555.4; = p.G280V on NM_031289.5) | Nonsense Mutation (SNP) | VAF 23/113 reads (20%) | catalogued as COSV52195572; called by muse, mutect2, varscan2
- GSK3A | c.850T>C p.Y284H | Missense Mutation (SNP) | VAF 49/168 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55899878; called by muse, mutect2, varscan2
- H1-8 | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT tolerated (0.53); PolyPhen benign (0.006); catalogued as rs1429634058, COSV60974204; called by muse, varscan2
- H2AC6 | c.377A>G p.K126R | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.095); catalogued as COSV58416710; called by muse, mutect2, varscan2
- H2AZ1 | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 49/168 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.577); catalogued as COSV56455554; called by muse, mutect2, varscan2
- HELZ2 | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as rs374328737; called by muse, varscan2
- HGF | c.1170T>G p.D390E | Missense Mutation (SNP) | VAF 130/374 reads (35%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as COSV55952143; called by muse, mutect2, varscan2
- HMCN1 | c.5720C>G p.T1907R | Missense Mutation (SNP) | VAF 52/162 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.34); catalogued as COSV54913961; called by muse, mutect2, varscan2
- HMCN1 | c.14957T>A p.L4986Q | Missense Mutation (SNP) | VAF 359/573 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV54913972; called by muse, mutect2, varscan2
- ILDR1 | c.1598C>G p.S533W (on ENST00000344209 / NM_001199799.2; = p.S489W on NM_175924.4) | Missense Mutation (SNP) | VAF 33/165 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV56551214; called by muse, mutect2, varscan2
- IMP4 | c.8G>A p.R3H | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as rs1441759402, COSV52092155; called by muse, mutect2
- ING4 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 11/237 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.155); catalogued as COSV58555522; called by muse, mutect2
- INPPL1 | c.2019G>A p.W673* | Nonsense Mutation (SNP) | VAF 71/110 reads (65%) | catalogued as COSV53355049; called by muse, mutect2, varscan2
- ITIH6 | c.1318C>T p.R440C | Missense Mutation (SNP) | VAF 87/165 reads (53%) | SIFT tolerated (0.19); PolyPhen benign (0.125); catalogued as rs772496720, COSV54490845; called by muse, mutect2, varscan2
- IVNS1ABP | c.953A>G p.H318R | Missense Mutation (SNP) | VAF 16/282 reads (6%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.777); catalogued as COSV62251469; called by muse, mutect2
- JAKMIP2 | c.2249C>T p.A750V | Missense Mutation (SNP) | VAF 172/656 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.345); catalogued as COSV54608526; called by muse, mutect2, varscan2
- KHDRBS2 | c.141G>C p.K47N | Missense Mutation (SNP) | VAF 88/542 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.164); catalogued as COSV55441329, COSV55467990, COSV55491198; called by muse, mutect2, varscan2
- KIAA0100 | c.3173G>A p.R1058Q | Missense Mutation (SNP) | VAF 32/52 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs759215125, COSV66494408; called by muse, mutect2, varscan2
- KIAA1549 | c.848del p.L283* | Frame Shift Del (DEL) | VAF 19/91 reads (21%) | catalogued as rs752375544, COSV54318481; called by mutect2, pindel, varscan2
- KRT6C | c.157G>T p.G53* | Nonsense Mutation (SNP) | VAF 24/126 reads (19%) | catalogued as COSV52878549; called by muse, mutect2
- LAMB1 | c.3482G>A p.R1161H | Missense Mutation (SNP) | VAF 36/188 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs774640720, COSV55966781, COSV55970049; called by muse, mutect2, varscan2
- LEPR | c.1448C>A p.S483Y | Missense Mutation (SNP) | VAF 125/465 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV100756326, COSV60758045; called by muse, mutect2, varscan2
- LIPT1 | c.368del p.K123Sfs*8 | Frame Shift Del (DEL) | VAF 24/102 reads (24%) | catalogued as rs780042765; called by mutect2, varscan2
- LRP5 | c.3241C>A p.L1081M | Missense Mutation (SNP) | VAF 32/45 reads (71%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV53718415; called by muse, mutect2, varscan2
- LRRC4C | c.1316C>T p.A439V | Missense Mutation (SNP) | VAF 134/203 reads (66%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.615); catalogued as COSV53430230; called by muse, mutect2, varscan2
- LRRTM1 | c.275C>T p.T92M | Missense Mutation (SNP) | VAF 33/165 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV54438525; called by muse, mutect2, varscan2
- LY9 | c.998G>A p.G333D | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54433150; called by muse, mutect2, varscan2
- MAGEA4 | c.275A>T p.E92V | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV52342096; called by muse, mutect2, varscan2
- MAN2A1 | c.2269G>T p.G757C | Missense Mutation (SNP) | VAF 31/162 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.298); catalogued as COSV54854334; called by muse, mutect2, varscan2
- MAS1 | c.365T>C p.L122P | Missense Mutation (SNP) | VAF 134/198 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53121582; called by muse, mutect2, varscan2
- MATN3 | c.1132G>A p.G378S | Missense Mutation (SNP) | VAF 98/223 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs566567939, COSV68100129; called by muse, mutect2, varscan2
- MCM3AP | c.3536G>A p.R1179H | Missense Mutation (SNP) | VAF 81/285 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.057); catalogued as rs750063536, COSV52441719; called by muse, mutect2, varscan2
- MED12L | c.1802T>C p.L601P | Missense Mutation (SNP) | VAF 103/422 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56385049; called by muse, mutect2, varscan2
- MED13 | c.1468G>A p.A490T | Missense Mutation (SNP) | VAF 19/515 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1260567078, COSV67264872; called by muse, mutect2
- MESD | c.632del p.K211Rfs*6 | Frame Shift Del (DEL) | VAF 148/304 reads (49%) | catalogued as rs745891632; called by mutect2, varscan2
- MGA | c.1054A>T p.I352F | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as COSV54957283; called by muse, mutect2, varscan2
- MIDEAS | c.939del p.N314Tfs*4 | Frame Shift Del (DEL) | VAF 17/52 reads (33%) | catalogued as rs762448666; called by mutect2, varscan2
- MNDA | c.776A>G p.K259R | Missense Mutation (SNP) | VAF 147/219 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV63741274; called by muse, mutect2, varscan2
- MRGPRF | c.776G>A p.W259* | Nonsense Mutation (SNP) | VAF 32/45 reads (71%) | catalogued as COSV57996165; called by muse, mutect2, varscan2
- MRPL32 | c.254G>A p.R85H | Missense Mutation (SNP) | VAF 52/323 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); catalogued as rs531271105, COSV56237150; called by muse, mutect2, varscan2
- MTUS2 | c.2534C>G p.P845R | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54990117; called by muse, mutect2, varscan2
- MUC16 | c.22163A>G p.E7388G | Missense Mutation (SNP) | VAF 79/249 reads (32%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.444); catalogued as COSV67476627; called by muse, mutect2, varscan2
- MUC16 | c.13030C>T p.Q4344* | Nonsense Mutation (SNP) | VAF 258/347 reads (74%) | catalogued as COSV67476636; called by mutect2, varscan2
- MUC16 | c.6760C>A p.P2254T | Missense Mutation (SNP) | VAF 17/237 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); catalogued as COSV67476642, COSV67480926; called by muse, mutect2
- MUC20 | c.2113C>T p.R705C | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs368425567, COSV57851926; called by muse, mutect2
- MVP | c.109C>T p.R37W | Missense Mutation (SNP) | VAF 47/157 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1391135647, COSV62422555; called by muse, mutect2, varscan2
- MXRA5 | c.5566C>T p.L1856F | Missense Mutation (SNP) | VAF 64/256 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as COSV54240523; called by muse, mutect2, varscan2
- MYC | c.227C>T p.A76V (on ENST00000377970; = p.A91V on NM_002467.6) | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.154); catalogued as COSV52373238; called by muse, mutect2
- MYCBP2 | c.11592C>A p.F3864L (on ENST00000357337; = p.F3902L on NM_015057.5) | Missense Mutation (SNP) | VAF 62/220 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV62026935; called by muse, varscan2
- MYO3B | c.3050C>A p.P1017H | Missense Mutation (SNP) | VAF 71/345 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100511422, COSV58708187; called by muse, mutect2, varscan2
- NAA20 | c.253C>T p.R85C | Missense Mutation (SNP) | VAF 275/675 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as rs753488560, COSV58548581; called by muse, mutect2, varscan2
- NAALADL2 | c.1787T>C p.I596T | Missense Mutation (SNP) | VAF 42/269 reads (16%) | SIFT tolerated (0.67); PolyPhen benign (0.089); catalogued as COSV71985481; called by muse, mutect2, varscan2
- NAV2 | c.1456C>T p.L486F (on ENST00000396087 / NM_001244963.2; = p.L463F on NM_145117.5) | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.997); catalogued as COSV62326724; called by muse, mutect2, varscan2
- NCKAP1 | c.1694A>G p.Y565C | Missense Mutation (SNP) | VAF 61/338 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV62941900; called by muse, mutect2, varscan2
- NCKAP5L | c.283C>T p.R95W | Missense Mutation (SNP) | VAF 76/349 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs367652218, COSV100259336; called by muse, mutect2, varscan2
- NDOR1 | c.143T>G p.L48R | Missense Mutation (SNP) | VAF 80/862 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59178434; called by muse, mutect2
- NEB | c.18918G>A p.S6306= | Splice Region (SNP) | VAF 255/571 reads (45%) | catalogued as rs1230102324, COSV51430461; called by muse, mutect2, varscan2
- NID2 | c.2307G>A p.M769I | Missense Mutation (SNP) | VAF 13/159 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV53498915; called by muse, mutect2
- NR1H2 | c.625C>A p.Q209K | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.86); PolyPhen benign (0.029); catalogued as COSV53801276; called by muse, mutect2, varscan2
- NR2F1 | c.1048T>G p.C350G | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV59069236; called by muse, mutect2, varscan2
- NUDT4 | c.203A>G p.Y68C | Missense Mutation (SNP) | VAF 156/309 reads (50%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV61464337; called by muse, mutect2, varscan2
- OPN1LW | c.112+2T>A p.X38_splice | Splice Site (SNP) | VAF 29/137 reads (21%) | catalogued as COSV64064633; called by muse, mutect2, varscan2
- OR13C9 | c.861G>A p.M287I | Missense Mutation (SNP) | VAF 26/448 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV52242738; called by muse, mutect2
- OR1M1 | c.150C>G p.S50R | Missense Mutation (SNP) | VAF 187/280 reads (67%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as COSV70037090; called by muse, mutect2, varscan2
- OR2G3 | c.224C>T p.T75I | Missense Mutation (SNP) | VAF 190/604 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV60682272; called by muse, mutect2, varscan2
- OR2M4 | c.634T>A p.S212T | Missense Mutation (SNP) | VAF 51/210 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as COSV60708770; called by muse, mutect2, varscan2
- OR5AS1 | c.117G>A p.M39I | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV57982330, COSV57982340; called by muse, mutect2, varscan2
- PCDHA11 | c.1205A>T p.N402I | Missense Mutation (SNP) | VAF 57/195 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV56519508; called by muse, mutect2, varscan2
- PCDHA12 | c.372G>T p.K124N | Missense Mutation (SNP) | VAF 42/236 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.467); catalogued as COSV56519519; called by muse, mutect2, varscan2
- PCDHA9 | c.2164C>T p.R722W | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.16); catalogued as rs782752701, COSV65327050; called by muse, mutect2, varscan2
- PCDHB11 | c.866G>A p.R289H | Missense Mutation (SNP) | VAF 120/271 reads (44%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.068); catalogued as COSV53380894; called by muse, mutect2, varscan2
- PCDHGA11 | c.1948C>G p.H650D | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.686); catalogued as COSV53977591; called by muse, mutect2, varscan2
- PDE10A | c.999-1G>A p.X333_splice | Splice Site (SNP) | VAF 102/284 reads (36%) | catalogued as COSV63100171; called by muse, mutect2, varscan2
- PGK1 | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 245/505 reads (49%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as COSV59371601; called by muse, mutect2, varscan2
- PHACTR1 | c.759dup p.P254Afs*78 | Frame Shift Ins (INS) | VAF 18/36 reads (50%) | catalogued as rs749326031; called by mutect2, varscan2
- PKDREJ | c.1980G>T p.Q660H | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1274793447, COSV53550469; called by muse, mutect2, varscan2
- PLA2G4E | c.1267C>T p.R423C | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.094); catalogued as rs200625247; called by muse, mutect2, varscan2
- PLG | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.237); catalogued as rs746890698, COSV51980879; called by muse, mutect2, varscan2
- PLSCR2 | c.686C>A p.A229E (on ENST00000497985 / NM_001199978.1; = p.A156E on NM_020359.2) | Missense Mutation (SNP) | VAF 126/516 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.025); catalogued as rs375128168, COSV60862312; called by muse, mutect2, varscan2
- PNMA8B | c.674C>T p.A225V | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV66537009; called by muse, mutect2, varscan2
- POC1B | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 50/220 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs538799207, COSV57966494; called by muse, mutect2, varscan2
- POU3F3 | c.1093G>A p.A365T | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100796893, COSV63721995; called by muse, mutect2, varscan2
- PROX1 | c.1939del p.V647Sfs*9 | Frame Shift Del (DEL) | VAF 52/238 reads (22%) | catalogued as COSV54782279; called by mutect2, pindel, varscan2
- PSIP1 | c.961C>A p.Q321K | Missense Mutation (SNP) | VAF 387/1014 reads (38%) | SIFT tolerated (0.5); PolyPhen benign (0.035); catalogued as COSV66255049; called by muse, varscan2
- PTEN | c.746T>A p.V249E | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV64299117, COSV64299288; called by muse, mutect2
- PTPN9 | c.1046G>A p.R349Q | Missense Mutation (SNP) | VAF 123/485 reads (25%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs758645507, COSV60724536; called by muse, mutect2, varscan2
- PTPRB | c.3671T>C p.L1224P | Missense Mutation (SNP) | VAF 56/242 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.864); catalogued as COSV54245400; called by muse, mutect2, varscan2
- PTPRS | c.4126G>A p.A1376T | Missense Mutation (SNP) | VAF 56/89 reads (63%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs200850387, COSV53611156; called by muse, mutect2, varscan2
- RAB40AL | c.709C>T p.R237* | Nonsense Mutation (SNP) | VAF 103/420 reads (25%) | catalogued as rs1268182246, COSV54433745; called by muse, mutect2, varscan2
- RNF216 | c.2512C>T p.R838W (on ENST00000425013 / NM_207116.3; = p.R895W on NM_207111.4) | Missense Mutation (SNP) | VAF 30/182 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs1181928002, COSV66290641; called by muse, mutect2
- RPL4 | c.851T>C p.M284T | Missense Mutation (SNP) | VAF 81/324 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV57181269; called by muse, mutect2, varscan2
- RPS6 | c.185C>A p.P62H | Missense Mutation (SNP) | VAF 47/72 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59548210; called by muse, mutect2, varscan2
- RUBCN | c.650C>A p.P217H | Missense Mutation (SNP) | VAF 45/904 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV56368553; called by muse, mutect2
- RYR2 | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 105/339 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as COSV63694854; called by muse, mutect2, varscan2
- RYR2 | c.14747C>A p.A4916D | Missense Mutation (SNP) | VAF 94/298 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63694861; called by muse, mutect2, varscan2
- SCN10A | c.986C>A p.S329Y | Missense Mutation (SNP) | VAF 151/245 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.072); catalogued as COSV71861986; called by muse, mutect2, varscan2
- SCN5A | c.4094A>G p.N1365S (on ENST00000333535 / NM_198056.3; = p.N1364S on NM_000335.5) | Missense Mutation (SNP) | VAF 227/343 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM1313356, COSV61129802; called by muse, mutect2, varscan2
- SCYL3 | c.1690G>T p.D564Y (on ENST00000367770; = p.D510Y on NM_020423.7) | Missense Mutation (SNP) | VAF 62/90 reads (69%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.45); catalogued as COSV53679591, COSV53680275; called by muse, mutect2, varscan2
- SELP | c.2438G>T p.S813I | Missense Mutation (SNP) | VAF 47/160 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV55254088, COSV55254973; called by muse, mutect2, varscan2
- SETD5 | c.1388A>G p.D463G | Missense Mutation (SNP) | VAF 86/281 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV56713405; called by muse, mutect2, varscan2
- SF1 | c.1328G>A p.G443D | Missense Mutation (SNP) | VAF 54/84 reads (64%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as COSV57113996; called by muse, mutect2, varscan2
- SH3TC2 | c.3699C>A p.Y1233* | Nonsense Mutation (SNP) | VAF 16/85 reads (19%) | catalogued as COSV60464818; called by muse, mutect2
- SHROOM4 | c.2203C>T p.Q735* | Nonsense Mutation (SNP) | VAF 13/88 reads (15%) | catalogued as COSV56792105, COSV99173305; called by muse, mutect2, varscan2
- SIGLEC7 | c.437T>C p.L146S | Missense Mutation (SNP) | VAF 121/182 reads (66%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV58316623; called by muse, mutect2, varscan2
- SIPA1L3 | c.3131G>A p.G1044D | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV55917882; called by muse, mutect2, varscan2
- SLAIN1 | c.1579G>A p.A527T (on ENST00000466548; = p.A264T on NM_144595.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.495); catalogued as rs768538431, COSV57387515; called by muse, mutect2, varscan2
- SLC19A3 | c.1051G>A p.V351I | Missense Mutation (SNP) | VAF 32/143 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV51453717; called by muse, mutect2, varscan2
- SLC35A4 | c.925G>A p.A309T | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.395); catalogued as COSV60053059; called by muse, mutect2, varscan2
- SLC38A11 | c.354A>G p.I118M (on ENST00000409149 / NM_001351539.1; = p.I96M on NM_173512.2) | Missense Mutation (SNP) | VAF 104/445 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.423); catalogued as COSV58054672; called by muse, mutect2, varscan2
- SLC38A2 | c.1001C>T p.A334V | Missense Mutation (SNP) | VAF 80/380 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.246); catalogued as COSV56745555; called by muse, mutect2, varscan2
- SLC46A3 | c.816del p.F272Lfs*3 | Frame Shift Del (DEL) | VAF 49/186 reads (26%) | catalogued as rs768002987; called by mutect2, pindel, varscan2
- SLC9C1 | c.29del p.F10Sfs*11 | Frame Shift Del (DEL) | VAF 38/210 reads (18%) | catalogued as rs749004401; called by mutect2, varscan2
- SNAPC4 | c.1003C>T p.Q335* | Nonsense Mutation (SNP) | VAF 54/164 reads (33%) | catalogued as COSV53734586; called by muse, mutect2, varscan2
- SNTG2 | c.1181G>A p.G394D | Missense Mutation (SNP) | VAF 44/162 reads (27%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.476); catalogued as COSV57991951; called by muse, varscan2
- SOX11 | c.158T>A p.M53K | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58986331; called by muse, mutect2
- SPHKAP | c.1927A>G p.M643V | Missense Mutation (SNP) | VAF 124/313 reads (40%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as rs1559350544, COSV60884464; called by muse, mutect2, varscan2
- STEAP3 | c.1462G>A p.V488I | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.058); catalogued as rs759879690, COSV61529700; called by muse, mutect2, varscan2
- STIL | c.3073G>A p.A1025T | Missense Mutation (SNP) | VAF 138/221 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767648577, COSV54551473; called by muse, mutect2, varscan2
- STMN2 | c.205C>T p.R69* | Nonsense Mutation (SNP) | VAF 52/247 reads (21%) | catalogued as COSV55220490; called by muse, mutect2, varscan2
- SYNE1 | c.13384G>A p.V4462M (on ENST00000367255 / NM_182961.4; = p.V4391M on NM_033071.3) | Missense Mutation (SNP) | VAF 74/213 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV55024044; called by muse, mutect2, varscan2
- TAF8 | c.373A>T p.T125S | Missense Mutation (SNP) | VAF 35/228 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.068); catalogued as COSV65896433; called by muse, mutect2, varscan2
- TAGAP | c.1165G>C p.E389Q | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as COSV57852429; called by muse, mutect2, varscan2
- TAS1R2 | c.1721C>A p.A574D | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.303); catalogued as COSV64745708; called by muse, mutect2, varscan2
- TCTE1 | c.284C>G p.P95R | Missense Mutation (SNP) | VAF 33/250 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101025396, COSV65255867; called by muse, mutect2, varscan2
- TCTE3 | c.240A>T p.K80N | Missense Mutation (SNP) | VAF 53/181 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV64655980; called by muse, mutect2, varscan2
- TENT5C | c.205G>A p.V69I | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as rs745917069, COSV65616345; called by muse, mutect2, varscan2
- TFAP2D | c.1169C>T p.A390V | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV50429999; called by muse, mutect2
- TGFBI | c.596A>G p.N199S | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.036); catalogued as rs756377536, COSV59352318; called by muse, mutect2, varscan2
- TLCD3A | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 52/164 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1258534982, COSV56746467; called by muse, mutect2, varscan2
- TLL1 | c.726G>T p.L242F | Missense Mutation (SNP) | VAF 246/423 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV50299831; called by muse, mutect2, varscan2
- TNRC18 | c.4342C>T p.R1448W | Missense Mutation (SNP) | VAF 46/110 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs563720153, COSV68166758; called by muse, mutect2, varscan2
- TP63 | c.1748A>T p.D583V | Missense Mutation (SNP) | VAF 43/197 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as CM095571, COSV53211099; called by muse, mutect2, varscan2
- TRIM28 | c.673G>A p.D225N | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53400928; called by muse, mutect2, varscan2
- TSR3 | c.907T>C p.W303R | Missense Mutation (SNP) | VAF 10/139 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV50104343; called by muse, mutect2
- TTC7B | c.1981A>G p.T661A | Missense Mutation (SNP) | VAF 36/64 reads (56%) | SIFT tolerated (0.05); PolyPhen benign (0.098); catalogued as COSV60634216; called by muse, mutect2, varscan2
- TTN | c.74009C>T p.P24670L (on ENST00000591111; = p.P17246L on NM_003319.4) | Missense Mutation (SNP) | VAF 33/130 reads (25%) | PolyPhen probably damaging (0.999); catalogued as COSV60164243; called by muse, mutect2, varscan2
- TUBGCP6 | c.2263A>T p.K755* | Nonsense Mutation (SNP) | VAF 50/77 reads (65%) | catalogued as COSV50556042; called by muse, mutect2, varscan2
- TVP23A | c.420del p.F140Lfs*7 | Frame Shift Del (DEL) | VAF 25/83 reads (30%) | catalogued as rs760251146; called by mutect2, varscan2
- UBR5 | c.6360del p.E2121Kfs*28 | Frame Shift Del (DEL) | VAF 128/714 reads (18%) | catalogued as rs763652408; called by mutect2, varscan2
- UHRF1BP1 | c.3820del p.L1274Wfs*39 | Frame Shift Del (DEL) | VAF 46/208 reads (22%) | catalogued as rs1444457394; called by mutect2, pindel, varscan2
- USP2 | c.1409G>A p.G470E | Missense Mutation (SNP) | VAF 10/257 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as COSV52730574; called by muse, mutect2
- USP35 | c.1962del p.T655Pfs*23 | Frame Shift Del (DEL) | VAF 86/274 reads (31%) | catalogued as rs764735138; called by mutect2, varscan2
- UTP3 | c.1156C>T p.Q386* | Nonsense Mutation (SNP) | VAF 9/108 reads (8%) | catalogued as COSV54661361; called by muse, mutect2
- VPS8 | c.2384C>A p.T795N (on ENST00000625842 / NM_001349294.1; = p.T793N on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/130 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as COSV54989597; called by muse, mutect2, varscan2
- VRK2 | c.1244G>A p.S415N | Missense Mutation (SNP) | VAF 35/200 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV52075672; called by muse, mutect2, varscan2
- WDFY3 | c.1247C>T p.A416V | Missense Mutation (SNP) | VAF 57/198 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.817); catalogued as rs752119815, COSV55699369; called by muse, mutect2, varscan2
- WDR59 | c.1636G>A p.G546R | Missense Mutation (SNP) | VAF 62/97 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs780289269, COSV50933490, COSV50937555; called by muse, mutect2, varscan2
- XIRP1 | c.3577C>T p.R1193W | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs371572701; called by muse, mutect2
- ZAN | c.4802C>T p.A1601V | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV61811102; called by muse, mutect2, varscan2
- ZC3H7B | c.989A>G p.K330R | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT tolerated (0.17); PolyPhen benign (0.125); catalogued as COSV60962996; called by muse, mutect2, varscan2
- ZDHHC19 | c.853T>C p.S285P | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.06); catalogued as rs373762265; called by muse, mutect2, varscan2
- ZFPM2 | c.2711G>A p.S904N | Missense Mutation (SNP) | VAF 31/184 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as COSV65874513; called by muse, mutect2, varscan2
- ZMAT3 | c.179A>T p.D60V | Missense Mutation (SNP) | VAF 61/513 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV60994136; called by muse, mutect2, varscan2
- ZNF10 | c.1061G>A p.C354Y | Missense Mutation (SNP) | VAF 42/330 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50213038; called by muse, mutect2, varscan2
- ZNF100 | c.1608G>C p.W536C | Missense Mutation (SNP) | VAF 52/172 reads (30%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.408); catalogued as COSV59748512; called by muse, mutect2, varscan2
- ZNF275 | c.670C>A p.L224I | Missense Mutation (SNP) | VAF 36/175 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV64704846; called by muse, mutect2, varscan2
- ZNF395 | c.1456T>C p.C486R | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1322205581, COSV60429371; called by muse, mutect2
- ZNF518B | c.914T>C p.L305P | Missense Mutation (SNP) | VAF 164/255 reads (64%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV58723332; called by muse, mutect2, varscan2
- ZNF607 | c.1840G>A p.D614N | Missense Mutation (SNP) | VAF 37/141 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.193); catalogued as COSV62205638; called by muse, mutect2, varscan2
- ZNF688 | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as COSV56301217; called by muse, mutect2, varscan2
- ZNF81 | c.1840G>A p.E614K | Missense Mutation (SNP) | VAF 59/309 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.046); catalogued as COSV58576976; called by muse, mutect2, varscan2
- ZXDA | c.1592C>T p.S531F | Missense Mutation (SNP) | VAF 66/370 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV62388298, COSV99080946; called by muse, mutect2, varscan2
- ABCA13 | c.8651dup p.C2885Lfs*14 | Frame Shift Ins (INS) | VAF 31/195 reads (16%) | called by mutect2, pindel, varscan2
- ADAP1 | c.440dup p.L147Ffs*21 | Frame Shift Ins (INS) | VAF 47/292 reads (16%) | called by mutect2, pindel, varscan2
- ARHGAP19 | c.135del p.F45Lfs*35 | Frame Shift Del (DEL) | VAF 26/142 reads (18%) | called by mutect2, pindel, varscan2
- BCL9 | c.2912del p.P971Hfs*11 | Frame Shift Del (DEL) | VAF 120/265 reads (45%) | called by mutect2, pindel, varscan2
- CEP126 | c.2325del p.G776Afs*22 | Frame Shift Del (DEL) | VAF 23/125 reads (18%) | called by mutect2, pindel, varscan2
- CHSY3 | c.959_961del p.E320del | In Frame Del (DEL) | VAF 103/463 reads (22%) | called by mutect2, pindel, varscan2
- CTSK | c.625_626del p.S209Lfs*11 | Frame Shift Del (DEL) | VAF 140/296 reads (47%) | called by pindel, varscan2
- DST | c.13036dup p.T4346Nfs*3 (on ENST00000361203 / NM_001374722.1; = p.T1934Nfs*3 on NM_015548.5) | Frame Shift Ins (INS) | VAF 148/362 reads (41%) | called by mutect2, pindel, varscan2
- FAT4 | c.2500del p.D834Ifs*20 | Frame Shift Del (DEL) | VAF 55/211 reads (26%) | called by mutect2, pindel, varscan2
- GARNL3 | c.311del p.L104* | Frame Shift Del (DEL) | VAF 77/275 reads (28%) | called by mutect2, pindel, varscan2
- GID4 | c.549dup p.H184Tfs*12 | Frame Shift Ins (INS) | VAF 91/363 reads (25%) | called by mutect2, pindel, varscan2
- HDAC6 | c.3098del p.P1033Qfs*17 | Frame Shift Del (DEL) | VAF 12/38 reads (32%) | called by mutect2, varscan2
- KEAP1 | c.1554dup p.I519Yfs*8 | Frame Shift Ins (INS) | VAF 33/66 reads (50%) | called by mutect2, pindel, varscan2
- KRT7 | c.704_705del p.E235Afs*28 | Frame Shift Del (DEL) | VAF 31/146 reads (21%) | called by pindel, varscan2
- OR8B4 | c.753dup p.G252Wfs*34 | Frame Shift Ins (INS) | VAF 48/246 reads (20%) | called by mutect2, pindel, varscan2
- PIK3R4 | c.493del p.T165Lfs*48 | Frame Shift Del (DEL) | VAF 131/357 reads (37%) | called by mutect2, pindel, varscan2
- RFX6 | c.2499del p.Y834Tfs*11 | Frame Shift Del (DEL) | VAF 66/212 reads (31%) | called by mutect2, pindel, varscan2
- RHOBTB2 | c.1593del p.P532Hfs*41 | Frame Shift Del (DEL) | VAF 24/122 reads (20%) | called by mutect2, varscan2
- SMARCA1 | c.2501del p.K834Rfs*50 | Frame Shift Del (DEL) | VAF 117/446 reads (26%) | called by mutect2, varscan2
- SNX2 | c.34del p.D12Tfs*24 | Frame Shift Del (DEL) | VAF 14/55 reads (25%) | called by mutect2, varscan2
- TAS2R42 | c.703dup p.M235Nfs*69 | Frame Shift Ins (INS) | VAF 39/176 reads (22%) | called by mutect2, pindel, varscan2
- TCEAL6 | c.468del p.K156Nfs*33 | Frame Shift Del (DEL) | VAF 319/907 reads (35%) | called by mutect2, pindel, varscan2
- UBQLN2 | c.1574del p.P525Lfs*71 | Frame Shift Del (DEL) | VAF 21/63 reads (33%) | called by mutect2, pindel, varscan2
- WDCP | c.1306_1308del p.E436del | In Frame Del (DEL) | VAF 66/326 reads (20%) | called by pindel, varscan2
- ABCC11 | c.2850C>T p.A950= | Silent (SNP) | VAF 102/163 reads (63%) | catalogued as rs951088516, COSV62324184; called by muse, mutect2, varscan2
- ADGRG2 | c.975C>T p.I325= (on ENST00000379869 / NM_001079858.3; = p.I322= on NM_005756.4) | Silent (SNP) | VAF 126/550 reads (23%) | catalogued as COSV61339971; called by muse, mutect2, varscan2
- ANK2 | c.3858T>C p.N1286= | Silent (SNP) | VAF 55/223 reads (25%) | catalogued as COSV52170803; called by muse, mutect2, varscan2
- ARHGAP21 | c.5691C>A p.G1897= | Silent (SNP) | VAF 303/464 reads (65%) | catalogued as COSV57607681; called by muse, mutect2, varscan2
- ARHGAP31 | c.2412G>A p.P804= | Silent (SNP) | VAF 29/79 reads (37%) | catalogued as rs776194035, COSV51789177; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ASMTL | c.1125C>T p.G375= | Silent (SNP) | VAF 135/658 reads (21%) | catalogued as COSV67244242; called by muse, mutect2, varscan2
- ASTN2 | c.2475C>T p.C825= (on ENST00000313400 / NM_001365069.1; = p.C774= on NM_014010.5) | Silent (SNP) | VAF 30/90 reads (33%) | catalogued as COSV57792045; called by muse, mutect2, varscan2
- ATP10B | c.2631G>T p.L877= | Silent (SNP) | VAF 70/136 reads (51%) | catalogued as COSV59156957; called by muse, mutect2, varscan2
- AURKC | c.850C>T p.L284= (on ENST00000302804 / NM_001015878.2; = p.L250= on NM_003160.3) | Silent (SNP) | VAF 122/188 reads (65%) | catalogued as rs1568485210, COSV57139103; called by muse, mutect2, varscan2
- C1RL | c.1311C>T p.G437= | Silent (SNP) | VAF 51/172 reads (30%) | catalogued as COSV56925761; called by muse, mutect2, varscan2
- CBLB | c.2283C>T p.S761= | Silent (SNP) | VAF 39/344 reads (11%) | catalogued as COSV51430214; called by muse, varscan2
- CCDC126 | c.99T>A p.T33= | Silent (SNP) | VAF 180/462 reads (39%) | catalogued as COSV56740436; called by muse, mutect2, varscan2
- CEBPE | c.828C>T p.G276= | Silent (SNP) | VAF 24/65 reads (37%) | catalogued as rs143753215; ClinVar: likely benign; called by muse, mutect2, varscan2
- CEBPG | c.435C>T p.G145= | Silent (SNP) | VAF 53/178 reads (30%) | catalogued as rs146371727; called by muse, mutect2, varscan2
- CEP350 | c.2256T>C p.A752= | Silent (SNP) | VAF 178/252 reads (71%) | catalogued as COSV62605099; called by muse, mutect2, varscan2
- CPXM1 | c.1332G>A p.L444= | Silent (SNP) | VAF 54/314 reads (17%) | catalogued as rs781466779, COSV66045982; called by muse, mutect2, varscan2
- CSTF1 | c.1248C>T p.S416= | Silent (SNP) | VAF 71/185 reads (38%) | catalogued as rs770162473, COSV53859278; called by muse, mutect2, varscan2
- CTBP2 | c.708C>T p.S236= | Silent (SNP) | VAF 67/262 reads (26%) | catalogued as rs746313497, COSV58335435; called by muse, mutect2, varscan2
- CYP4B1 | c.6G>A p.V2= | Silent (SNP) | VAF 153/241 reads (63%) | catalogued as COSV54724415; called by muse, mutect2, varscan2
- DBF4 | c.408A>G p.L136= | Silent (SNP) | VAF 85/530 reads (16%) | catalogued as COSV55997412; called by muse, mutect2, varscan2
- EFNB1 | c.292T>C p.L98= | Silent (SNP) | VAF 43/193 reads (22%) | catalogued as COSV52662103; called by muse, mutect2, varscan2
- EIF4E | c.66G>A p.T22= | Silent (SNP) | VAF 119/453 reads (26%) | catalogued as rs771705281, COSV55187893; called by muse, mutect2, varscan2
- EPPK1 | c.5520G>T p.T1840= | Silent (SNP) | VAF 384/973 reads (39%) | catalogued as rs1477733044, COSV73261416, COSV73261714; called by muse, mutect2, varscan2
- FAM126B | c.1017G>A p.E339= | Silent (SNP) | VAF 56/274 reads (20%) | catalogued as COSV53773579; called by muse, mutect2, varscan2
- FBN1 | c.4257G>A p.Q1419= | Silent (SNP) | VAF 30/152 reads (20%) | catalogued as COSV57321579; called by muse, mutect2, varscan2
- FKBP10 | c.1722C>T p.D574= | Silent (SNP) | VAF 26/94 reads (28%) | catalogued as rs782606571, COSV54056570; called by muse, mutect2, varscan2
- GABRB2 | c.1185G>A p.L395= | Silent (SNP) | VAF 63/331 reads (19%) | catalogued as rs771655720, COSV50916238, COSV50921955; called by muse, mutect2, varscan2
- GLIPR1L1 | c.222G>A p.Q74= | Silent (SNP) | VAF 75/253 reads (30%) | catalogued as COSV56882557; called by muse, mutect2, varscan2
- GMDS | c.948C>T p.H316= | Silent (SNP) | VAF 93/350 reads (27%) | catalogued as rs931855958, COSV66415136; called by muse, mutect2, varscan2
- GPR119 | c.678T>G p.T226= | Silent (SNP) | VAF 74/182 reads (41%) | catalogued as COSV52275964; called by muse, mutect2, varscan2
- GREM2 | c.384C>T p.V128= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV58953052; called by muse, mutect2
- GRIN2A | c.2460A>T p.V820= | Silent (SNP) | VAF 34/85 reads (40%) | catalogued as COSV58041875; called by muse, mutect2, varscan2
- HECTD4 | c.10464C>T p.S3488= | Silent (SNP) | VAF 25/72 reads (35%) | catalogued as COSV66394580; called by muse, mutect2, varscan2
- HPS4 | c.603C>A p.V201= | Silent (SNP) | VAF 106/163 reads (65%) | catalogued as COSV61104143; called by muse, mutect2, varscan2
- IKBKB | c.1320G>A p.L440= | Silent (SNP) | VAF 11/90 reads (12%) | catalogued as rs761172279, COSV60598258; called by muse, mutect2
- INTS2 | c.3591A>T p.I1197= | Silent (SNP) | VAF 45/160 reads (28%) | catalogued as COSV52002209; called by muse, mutect2, varscan2
- KCNK3 | c.426C>T p.R142= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as rs368608175; called by muse, mutect2, varscan2
- KCTD18 | c.81G>A p.R27= | Silent (SNP) | VAF 47/173 reads (27%) | catalogued as COSV63344621; called by muse, mutect2, varscan2
- KIF3C | c.624C>T p.H208= | Silent (SNP) | VAF 24/105 reads (23%) | catalogued as COSV53100349; called by muse, mutect2, varscan2
- KRTAP11-1 | c.438G>T p.G146= | Silent (SNP) | VAF 25/66 reads (38%) | catalogued as COSV60094788; called by muse, mutect2, varscan2
- LANCL2 | c.636A>G p.T212= | Silent (SNP) | VAF 95/556 reads (17%) | catalogued as COSV54650375; called by muse, mutect2, varscan2
- LEO1 | c.138T>C p.D46= | Silent (SNP) | VAF 107/459 reads (23%) | catalogued as COSV55176332; called by muse, mutect2, varscan2
- LRP12 | c.1455C>T p.C485= | Silent (SNP) | VAF 74/495 reads (15%) | catalogued as COSV52630556; called by muse, mutect2, varscan2
- LRRC73 | c.690A>C p.T230= | Silent (SNP) | VAF 45/359 reads (13%) | catalogued as COSV52501837; called by muse, mutect2, varscan2
- LYNX1 | c.72C>T p.H24= | Silent (SNP) | VAF 46/178 reads (26%) | catalogued as rs775935859, COSV59989357; called by muse, mutect2, varscan2
- MARS1 | c.756C>G p.P252= | Silent (SNP) | VAF 111/269 reads (41%) | catalogued as COSV56256541; called by muse, mutect2, varscan2
- MS4A14 | c.636C>T p.L212= | Silent (SNP) | VAF 16/336 reads (5%) | catalogued as COSV55736056; called by muse, mutect2
- MUC16 | c.3330C>T p.V1110= | Silent (SNP) | VAF 69/234 reads (29%) | catalogued as COSV67476647; called by muse, mutect2, varscan2
- MYO7B | c.4582C>T p.L1528= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as COSV67349037; called by muse, mutect2, varscan2
- NEDD1 | c.537C>T p.G179= | Silent (SNP) | VAF 68/297 reads (23%) | catalogued as rs199889686, COSV57144515; called by muse, mutect2, varscan2
- NEFL | c.1158T>C p.I386= | Silent (SNP) | VAF 272/717 reads (38%) | catalogued as COSV55337479; called by muse, varscan2
- NFYC | c.315T>C p.I105= | Silent (SNP) | VAF 110/326 reads (34%) | catalogued as COSV58128102; called by muse, mutect2, varscan2
- NIM1K | c.357C>T p.S119= | Silent (SNP) | VAF 73/332 reads (22%) | catalogued as COSV58143084; called by muse, mutect2, varscan2
- NPRL3 | c.1605G>A p.T535= (on ENST00000611875 / NM_001077350.3; = p.T510= on NM_001039476.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 50/73 reads (68%) | catalogued as rs775180844, COSV54738378, COSV54738835; called by muse, mutect2, varscan2
- NXPE3 | c.1608G>A p.L536= | Silent (SNP) | VAF 21/109 reads (19%) | catalogued as COSV56290748; called by muse, mutect2, varscan2
- OR10K1 | c.711C>A p.T237= | Silent (SNP) | VAF 66/249 reads (27%) | catalogued as COSV56872515; called by muse, mutect2, varscan2
- OR4N2 | c.51G>C p.L17= | Silent (SNP) | VAF 149/242 reads (62%) | catalogued as rs1448172121, COSV60052641, COSV60054197; called by muse, mutect2, varscan2
- OR51B4 | c.246C>T p.V82= | Silent (SNP) | VAF 25/195 reads (13%) | catalogued as COSV66517417; called by muse, mutect2, varscan2
- P3H2 | c.657A>G p.K219= | Silent (SNP) | VAF 48/294 reads (16%) | catalogued as COSV60023737; called by muse, mutect2
- PCDHB3 | c.2181G>A p.V727= | Silent (SNP) | VAF 20/101 reads (20%) | catalogued as COSV50586966; called by muse, mutect2, varscan2
- PCNX3 | c.2052C>T p.Y684= | Silent (SNP) | VAF 31/88 reads (35%) | catalogued as rs368034012; called by muse, mutect2, varscan2
- PKN2 | c.558A>G p.K186= | Silent (SNP) | VAF 145/225 reads (64%) | catalogued as COSV60132714; called by muse, mutect2, varscan2
- PLA2G4D | c.660C>T p.S220= | Silent (SNP) | VAF 31/110 reads (28%) | catalogued as rs568703242, COSV51821843; called by muse, mutect2, varscan2
- PLCL1 | c.2277G>A p.A759= | Silent (SNP) | VAF 46/198 reads (23%) | catalogued as rs1253640089, COSV70843301; called by muse, mutect2, varscan2
- PLK2 | c.1227G>A p.Q409= | Silent (SNP) | VAF 156/680 reads (23%) | catalogued as COSV57108318; called by muse, mutect2, varscan2
- POF1B | c.1680C>T p.L560= | Silent (SNP) | VAF 145/658 reads (22%) | catalogued as COSV53136250; called by muse, mutect2, varscan2
- PPP2R2A | c.993T>C p.S331= | Silent (SNP) | VAF 112/573 reads (20%) | catalogued as COSV60097913; called by muse, mutect2, varscan2
- PSG11 | c.354A>G p.G118= | Silent (SNP) | VAF 181/672 reads (27%) | catalogued as COSV60456243; called by muse, mutect2, varscan2
- PSG8 | c.165C>T p.V55= | Silent (SNP) | VAF 260/772 reads (34%) | catalogued as rs1300725850, COSV60613151; called by muse, mutect2, varscan2
- PSMA3 | c.369T>C p.Y123= | Silent (SNP) | VAF 86/301 reads (29%) | catalogued as rs1238486495, COSV53617548; called by muse, mutect2, varscan2
- PTCHD1 | c.165G>A p.L55= | Silent (SNP) | VAF 20/85 reads (24%) | catalogued as rs1463193460, COSV65061460; called by muse, mutect2, varscan2
- PTPN11 | c.1683G>A p.P561= | Silent (SNP) | VAF 37/144 reads (26%) | catalogued as rs397516798, COSV61010405; ClinVar: likely benign; called by muse, mutect2, varscan2
- PTPRZ1 | c.399C>T p.C133= | Silent (SNP) | VAF 66/372 reads (18%) | catalogued as COSV66437628, COSV66440436; called by muse, mutect2, varscan2
- RAB11FIP1 | c.570C>T p.S190= | Silent (SNP) | VAF 314/815 reads (39%) | catalogued as rs563868240, COSV54761452; called by muse, mutect2, varscan2
- RNF13 | c.264T>C p.N88= | Silent (SNP) | VAF 128/397 reads (32%) | catalogued as COSV60132336; called by muse, mutect2, varscan2
- SIX2 | c.768A>G p.P256= | Silent (SNP) | VAF 47/181 reads (26%) | catalogued as COSV57391428; called by muse, mutect2, varscan2
- SLC36A1 | c.1113G>A p.E371= | Silent (SNP) | VAF 126/515 reads (24%) | catalogued as COSV54654872; called by muse, mutect2, varscan2
- SLC37A1 | c.816G>A p.K272= | Silent (SNP) | VAF 49/177 reads (28%) | catalogued as COSV61403142; called by muse, mutect2, varscan2
- SRD5A1 | c.489G>A p.L163= | Silent (SNP) | VAF 110/526 reads (21%) | catalogued as COSV57013330, COSV57014523; called by muse, mutect2, varscan2
- TACC1 | c.1207C>T p.L403= | Silent (SNP) | VAF 59/283 reads (21%) | catalogued as COSV52525910; called by muse, mutect2, varscan2
- TECTA | c.4350C>T p.R1450= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as rs529744148, COSV50736491; called by muse, mutect2, varscan2
- THSD7B | c.4026A>G p.A1342= (on ENST00000272643; = p.A1340= on NM_001316349.2) | Silent (SNP) | VAF 117/266 reads (44%) | catalogued as COSV55706086; called by muse, mutect2, varscan2
- TNRC6A | c.732C>T p.G244= | Silent (SNP) | VAF 8/123 reads (7%) | catalogued as COSV59366836; called by muse, mutect2
- TRAF3IP1 | c.822G>A p.G274= | Silent (SNP) | VAF 130/603 reads (22%) | catalogued as COSV64853314; called by muse, mutect2, varscan2
- TRIM9 | c.1371C>T p.S457= | Silent (SNP) | VAF 75/249 reads (30%) | catalogued as rs544784389, COSV53615935; called by muse, mutect2, varscan2
- TTC37 | c.4611G>A p.E1537= | Silent (SNP) | VAF 14/249 reads (6%) | catalogued as COSV62455462; called by muse, mutect2
- UTP23 | c.555G>A p.V185= | Silent (SNP) | VAF 37/207 reads (18%) | catalogued as COSV59124600, COSV59125036; called by muse, mutect2, varscan2
- VRTN | c.120C>A p.S40= | Silent (SNP) | VAF 29/91 reads (32%) | catalogued as COSV56442025; called by muse, mutect2, varscan2
- WRAP53 | c.234C>T p.P78= | Silent (SNP) | VAF 65/113 reads (58%) | catalogued as COSV53212797; called by muse, mutect2, varscan2
- XKR5 | c.804C>T p.Y268= | Silent (SNP) | VAF 28/147 reads (19%) | catalogued as rs1326836228, COSV68398454, COSV68398679; called by muse, varscan2
- ZBTB34 | c.552G>A p.T184= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as rs542112678, COSV59860204; called by muse, mutect2, varscan2
- ZFP64 | c.795C>T p.S265= | Silent (SNP) | VAF 31/106 reads (29%) | catalogued as rs766045900, COSV53796412; called by muse, mutect2, varscan2
- ZHX2 | c.1044G>A p.L348= | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as COSV58714484; called by muse, mutect2, varscan2
- ZNF460 | c.750G>A p.K250= | Silent (SNP) | VAF 28/99 reads (28%) | catalogued as COSV64415934; called by muse, mutect2, varscan2
- ZNF646 | c.5157T>G p.L1719= | Silent (SNP) | VAF 82/106 reads (77%) | catalogued as rs1219869661, COSV54925270; called by muse, mutect2, varscan2
- ZNF808 | c.1755T>C p.H585= | Silent (SNP) | VAF 18/93 reads (19%) | catalogued as COSV63120501; called by muse, mutect2, varscan2
- AC073310.1 | n.703T>A | RNA (SNP) | VAF 97/546 reads (18%) | called by muse, mutect2, varscan2
- ACP1 | c.231+86G>A | Intron (SNP) | VAF 96/430 reads (22%) | catalogued as COSV55243941, COSV55244300, COSV55244789; called by muse, mutect2
- MIR450A1 | n.47A>G | RNA (SNP) | VAF 148/587 reads (25%) | called by muse, mutect2, varscan2
- SLC35A2 | c.1163+97C>T | Intron (SNP) | VAF 33/123 reads (27%) | catalogued as COSV54430934; called by muse, mutect2, varscan2
- WASF4P | n.1416G>A | RNA (SNP) | VAF 76/357 reads (21%) | called by muse, mutect2, varscan2
